Surgical pathology report (de-identified scan), TCGA case TCGA-DK-AA6M, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-AA6M-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Gender: F

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

year old female, history of TCC in , TCC Ta HG, after 6x BCG, now with bladder tumor

Specimens Submitted:

1: Bladder, right lateral wall, TURB

DIAGNOSIS:

1. Bladder, right lateral wall, TURB:

Tumor Type:

Invasive urothelial carcinoma, NOS
with sarcomatoid and anaplastic features

Histologic Grade:

High grade

Pattern of growth of the non-invasive component:

Flat (in situ carcinoma)

Local Invasion:

Muscularis propria

Vascular Invasion:

Not identified

ICD.O-3
Carcinoma, urothelial NOS 8120/3
Site Bladder, lateral wall
167.2
GJ 4/20/14

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received in . labeled "right lateral wall", and consists of multiple pieces of tan soft tissue measuring 3.0 x 2.0 x 0.7 cm in aggregate. The specimen is entirely submitted in two cassettes.

Summary of Sections:

Part 1: Bladder, right lateral wall, TURB

[page 2 of 2]
Blocks	Block Designation	PCs
2		2

BC6 > 90 days
to procurement.

Source: NCI Genomic Data Commons file 06149a76-4ff8-49c0-b216-f282fe1da94f (TCGA-DK-AA6M.C1106CFA-9382-4748-927C-E46BA18D4991.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).